Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9K0, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9K0-01A (Primary Tumor).

ICD 0.3
Carcinoma, papillary renal cell 8260/3
Site: (R) Kidney NOS C64.9
5/6/13/14

Report of pathology by phone:

1) A Papillary Renal Cell Carcinoma, Type I of 3.6 cm in diameter, well differentiated. The surrounding Kidney parenchyma is free of tumor.

Stage: pT1a, pNX, pMX, R0

Grade: GII

ICD-O-Code: 8260/3

Laterality = (R)

Source: NCI Genomic Data Commons file 691a6512-17e0-43e9-830c-8a31163ae796 (TCGA-5P-A9K0.E9C2193B-C508-40A9-99B4-070C38332B00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).